Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3982, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3982-01A (Primary Tumor).

This is an unequivocal finding in the sense of an adenocarcinoma of the colon with extensive necrosis and poor differentiation (thus corresponding to G3) with penetration of all parietal layers and vascular infiltration (thus corresponding to pT3, L1, V1) with free resection margins in the mucosal region with a regular mucosa, submucosa and muscularis and free resection margins in the mesenchymal region and three lymph node metastases (corresponding to pN1). In addition, there were diverticular formations.

Tumor classification:

ICDO-DA-M

G 3

pT3

L1, V1

pN1 (3 of 13 lymph nodes)

Source: NCI Genomic Data Commons file de057976-c334-4712-ab68-7953ca47a2a1 (TCGA-AA-3982.98BB6188-7493-47AF-A8DA-99929E1EA542.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).